Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHV, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHV-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 7.0 cm; no invasion of rete testis; no angio-invasion;
no invasion of tunica albuginea; epididymis free of tumor; surgical margin spermatic cord free
of tumor.

Date of procurement (= date of orchidectomy):

ICD-O-3
Seminoma NOS 9061/3
Site: (L) Testis NOS 602.0
JAS 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 5ae8d2ae-2c64-48b2-b372-bff6b7bc95f0 (TCGA-2G-AAHV-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).